Somatic mutation profile of tumor specimen TCGA-29-1762-01A (aliquot TCGA-29-1762-01A-01W-0633-09) from TCGA case TCGA-29-1762, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 59.9 years (21,879 days).
Specimen TCGA-29-1762-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a721ea8-f512-4ece-bf78-77702755f2b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1762-10A (Blood Derived Normal), aliquot TCGA-29-1762-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23b66713-f81b-48c1-84d2-20c69ca5632b

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 16, Nonsense Mutation 9, Frame Shift Ins 4, Frame Shift Del 3, In Frame Del 2, Splice Site 1, RNA 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 58/78 reads (74%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY3 | c.2927C>T p.T976I | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53173384; called by muse, mutect2, varscan2
- ARHGEF38 | c.271A>C p.M91L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV99486327; called by muse, mutect2
- ATRIP | c.1312G>C p.A438P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs775066454, COSV56498217; called by muse, mutect2, varscan2
- AURKB | c.475dup p.R159Pfs*15 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | catalogued as rs745673717; called by pindel, varscan2
- BRCA2 | c.8716G>T p.E2906* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as COSV66463511; called by muse, mutect2, varscan2
- C8orf34 | c.1188C>A p.Y396* | Nonsense Mutation (SNP) | VAF 10/204 reads (5%) | catalogued as COSV100298287; called by muse, mutect2
- CASQ2 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.633); catalogued as COSV54770141, COSV54774506; called by muse, mutect2, varscan2
- CCR8 | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58338125; called by muse, mutect2, varscan2
- CFAP47 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52892636; called by muse, mutect2, varscan2
- CHRDL1 | c.870G>C p.E290D (on ENST00000372045; = p.E296D on NM_145234.4) | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV54329431; called by muse, mutect2, varscan2
- CLBA1 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66348623; called by muse, mutect2
- COQ6 | c.1176C>A p.H392Q | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53180474; called by muse, mutect2, varscan2
- DLGAP2 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.5); PolyPhen benign (0.299); catalogued as rs545241585, COSV101422136, COSV70102290; called by muse, mutect2, varscan2
- DLGAP3 | c.1130dup p.Y378Lfs*27 | Frame Shift Ins (INS) | VAF 16/130 reads (12%) | catalogued as rs748374796; called by mutect2, varscan2
- DNAH2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV50021527; called by muse, mutect2, varscan2
- EHHADH | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs1476711264, COSV99213196; called by muse, mutect2
- ERGIC3 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99650432; called by muse, mutect2, varscan2
- FAT4 | c.9974G>C p.S3325T | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.986); catalogued as COSV58711797; called by muse, mutect2, varscan2
- FCGR2C | c.810A>T p.Q270H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.666); catalogued as COSV63439428, COSV63442573; called by muse, mutect2, varscan2
- FN1 | c.6993C>A p.D2331E (on ENST00000359671 / NM_001365524.2; = p.D2300E on NM_002026.4) | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.992); catalogued as rs150636748; called by muse, mutect2, varscan2
- GAD2 | c.1237G>T p.G413* | Nonsense Mutation (SNP) | VAF 29/123 reads (24%) | catalogued as COSV52169918; called by muse, mutect2, varscan2
- IL1RAPL1 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100149315, COSV56306090; called by muse, mutect2, varscan2
- ITGA2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56868554, COSV99670856; called by muse, mutect2
- ITGA8 | c.2287A>T p.R763* | Nonsense Mutation (SNP) | VAF 35/63 reads (56%) | catalogued as COSV65231274, COSV65237160; called by muse, mutect2, varscan2
- ITPRID2 | c.1513C>A p.H505N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775262552, COSV57477080; called by muse, mutect2, varscan2
- KLB | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57305649; called by muse, mutect2, varscan2
- LAMC2 | c.1067-2A>C p.X356_splice | Splice Site (SNP) | VAF 119/299 reads (40%) | catalogued as COSV51460201; called by muse, mutect2, varscan2
- LAT2 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); catalogued as COSV51922952; called by muse, mutect2, varscan2
- LCE1F | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57670377; called by muse, mutect2, varscan2
- LIPH | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 105/422 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV56186682; called by muse, mutect2, varscan2
- LRRC43 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV60293761; called by muse, mutect2, varscan2
- MAP3K2 | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV61296662; called by muse, mutect2, varscan2
- METTL21A | c.481C>G p.H161D | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV55882219; called by muse, mutect2, varscan2
- MFSD14B | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs201761715, COSV64702227; called by muse, mutect2, varscan2
- MFSD6 | c.1137G>T p.M379I | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55625915; called by muse, mutect2, varscan2
- MYOCD | c.684dup p.S229Qfs*17 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs760792013; called by mutect2, varscan2
- NPR1 | c.1840T>C p.Y614H | Missense Mutation (SNP) | VAF 197/436 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64118242; called by muse, varscan2
- NRIP3 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV58470678, COSV58471451; called by muse, mutect2, varscan2
- OR2D2 | c.473T>G p.V158G | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV55058466; called by muse, mutect2, varscan2
- PHLDB2 | c.3368G>A p.R1123Q (on ENST00000393925 / NM_001134439.2; = p.R1080Q on NM_145753.2) | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs758857139, COSV67316573; called by muse, mutect2, varscan2
- PIK3R1 | c.1695C>A p.S565R (on ENST00000521381 / NM_181523.3; = p.S295R on NM_181504.4) | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV57130678, COSV57141366; called by muse, mutect2, varscan2
- PLG | c.1001G>A p.W334* | Nonsense Mutation (SNP) | VAF 61/78 reads (78%) | catalogued as COSV51986863; called by muse, mutect2, varscan2
- SERPINE3 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV68545957; called by muse, mutect2, varscan2
- SULT1C4 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 172/444 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as COSV55599165; called by muse, mutect2, varscan2
- SYT10 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 93/192 reads (48%) | catalogued as COSV57346145; called by muse, mutect2, varscan2
- TGIF2 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV100872296; called by muse, mutect2, varscan2
- TMEM143 | c.124dup p.R42Pfs*86 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs762159291; called by mutect2, varscan2
- TMPRSS4 | c.765C>G p.N255K | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.124); catalogued as COSV71110697; called by muse, mutect2, varscan2
- VPS51 | c.1882G>C p.G628R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54209682; called by muse, mutect2, varscan2
- VSNL1 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99723089; called by muse, mutect2
- WARS1 | c.915C>A p.C305* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV59927957; called by muse, mutect2, varscan2
- ZNF552 | c.965G>C p.R322T | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV66971985; called by muse, mutect2, varscan2
- ZNF592 | c.2707C>T p.Q903* | Nonsense Mutation (SNP) | VAF 13/20 reads (65%) | catalogued as COSV55440057; called by muse, mutect2, varscan2
- ZNF638 | c.4703C>G p.T1568S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52498056; called by muse, mutect2, varscan2
- HAT1 | c.1118_1134del p.M373Tfs*18 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
- IGHG3 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 178/610 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- L1TD1 | c.1413_1421del p.D471_V473del | In Frame Del (DEL) | VAF 49/137 reads (36%) | called by mutect2, pindel, varscan2
- SLC16A13 | c.967_975del p.P323_A325del | In Frame Del (DEL) | VAF 36/50 reads (72%) | called by mutect2, pindel, varscan2
- SPRY1 | c.14del p.N5Ifs*9 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel
- XPO4 | c.819_820del p.R273Sfs*40 | Frame Shift Del (DEL) | VAF 30/55 reads (55%) | called by pindel, varscan2
- ATG2A | c.2085A>G p.E695= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1399406515, COSV65969068; called by muse, mutect2, varscan2
- DMD | c.2280A>G p.K760= | Silent (SNP) | VAF 78/174 reads (45%) | catalogued as COSV55905396; called by muse, mutect2, varscan2
- EHHADH | c.1578G>A p.G526= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs150207107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD3 | c.4137C>G p.P1379= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV52197910; called by muse, mutect2, varscan2
- HPS6 | c.1005G>C p.L335= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV54626896; called by muse, mutect2, varscan2
- LRCH2 | c.981A>G p.S327= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV57761294; called by muse, mutect2, varscan2
- PLEKHA7 | c.2544T>A p.P848= | Silent (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2
- RAD54B | c.78T>C p.S26= | Silent (SNP) | VAF 109/141 reads (77%) | catalogued as COSV52596072; called by muse, mutect2, varscan2
- SAE1 | c.1005G>A p.K335= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs56405554, COSV99537947; called by muse, mutect2, varscan2
- SUCNR1 | c.846T>G p.P282= | Silent (SNP) | VAF 81/223 reads (36%) | catalogued as COSV62912881; called by muse, mutect2, varscan2
- THEM5 | c.288G>T p.R96= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV64313281; called by muse, mutect2, varscan2
- TNFAIP1 | c.945C>A p.R315= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs782728946, COSV99134788; called by muse, mutect2
- XIRP1 | c.3657C>T p.L1219= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV61141753; called by muse, mutect2, varscan2
- ZFHX4 | c.2962T>C p.L988= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV99263048; called by muse, mutect2
- ZNF418 | c.477T>A p.S159= | Silent (SNP) | VAF 155/183 reads (85%) | catalogued as COSV68676579; called by muse, mutect2, varscan2
- ZNF710 | c.1381C>A p.R461= | Silent (SNP) | VAF 8/137 reads (6%) | catalogued as COSV99184147; called by muse, mutect2
- ALMS1P1 | chr2:73701157 ins C | 3'Flank (INS) | VAF 13/91 reads (14%) | catalogued as rs760920589; called by mutect2, varscan2
- OR2W5 | n.1207G>A | RNA (SNP) | VAF 101/170 reads (59%) | called by muse, mutect2, varscan2
- PHACTR1 | c.664+2190C>T | Intron (SNP) | VAF 61/142 reads (43%) | catalogued as rs541413328, COSV60683790; called by mutect2, varscan2
